Somatic mutation profile of cancer-model specimen HCM-CSHL-0670-C18-85M (3D Organoid, passage 2; aliquot HCM-CSHL-0670-C18-85M-01D-A85C-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0670-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Age at diagnosis: 54.2 years (19,808 days).
Specimen HCM-CSHL-0670-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea6472db-9864-4e47-b34f-1ca9dd6be021.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0670-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0670-C18-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e096502-c48d-4657-8662-6155dd48d085

The open-access MAF lists 341 somatic variants for this specimen: 243 protein-altering or splice-affecting, 88 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 216, Silent 88, Nonsense Mutation 16, Intron 8, Splice Region 3, Frame Shift Ins 3, In Frame Del 2, 3'UTR 1, RNA 1, Splice Site 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 289/289 reads (100%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0A4 | c.816+1G>A p.X272_splice | Splice Site (SNP) | VAF 132/184 reads (72%) | catalogued as rs1450564765; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TH | c.457C>T p.R153* (on ENST00000381178 / NM_199292.3; = p.R122* on NM_000360.4) | Nonsense Mutation (SNP) | VAF 754/894 reads (84%) | catalogued as rs771610752, CM101636; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 256/256 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.3224C>T p.T1075M (on ENST00000614293; = p.T1045M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 276/384 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1201870585; called by muse, mutect2, varscan2
- ACO1 | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1214446348; called by muse, varscan2
- ACSM4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 199/389 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs79217312, COSV68066927, COSV68069170; called by muse, mutect2, varscan2
- ADAMTS10 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 238/410 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555736477; called by muse, varscan2
- ADGRB1 | c.4118C>T p.P1373L | Missense Mutation (SNP) | VAF 106/626 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60102561; called by muse, mutect2, varscan2
- ADORA3 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 146/148 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53986718; called by muse, varscan2
- ALPP | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 237/626 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548067465; called by muse, varscan2
- ANO5 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 46/372 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV61087808; called by muse, mutect2, varscan2
- ASIC1 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 106/392 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57320939; called by muse, mutect2, varscan2
- ATF2 | c.102G>A p.Q34= | Splice Region (SNP) | VAF 24/244 reads (10%) | catalogued as rs943481632, COSV99908904; called by muse, varscan2
- BCL2L13 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.759); catalogued as rs1314051458; called by muse, mutect2, varscan2
- BFSP2 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 141/546 reads (26%) | catalogued as rs752114772, COSV56588540; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 172/441 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63244561; called by muse, mutect2, varscan2
- C17orf97 | c.799_828del p.P267_H276del | In Frame Del (DEL) | VAF 7/78 reads (9%) | catalogued as rs1567570475; called by pindel, varscan2*
- C19orf38 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 305/554 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs779753450, COSV67318846; called by muse, varscan2
- C1RL | c.1146G>T p.M382I | Missense Mutation (SNP) | VAF 98/388 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV56927172; called by muse, varscan2
- C4orf54 | c.2359G>A p.G787S | Missense Mutation (SNP) | VAF 300/396 reads (76%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); catalogued as rs1313711730; called by muse, mutect2, varscan2
- CCDC169 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53487812; called by muse, varscan2
- CCDC3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 354/607 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs371834557; called by muse, mutect2, varscan2
- CDH4 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 89/765 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556825432, COSV64650628; called by muse, varscan2
- CNNM3 | c.2002C>T p.Q668* | Nonsense Mutation (SNP) | VAF 182/476 reads (38%) | catalogued as rs768728722; called by muse, varscan2
- CPA1 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 154/539 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV50569686; called by muse, varscan2
- CYRIA | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62863615; called by muse, mutect2, varscan2
- DDX23 | c.1474G>T p.G492W | Missense Mutation (SNP) | VAF 80/435 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100339907; called by muse, mutect2, varscan2
- DMXL1 | c.8348G>A p.R2783Q | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs765866496; called by muse, varscan2
- DPYD | c.863C>G p.P288R | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV64615652; called by muse, mutect2, varscan2
- DYSF | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 70/500 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs376358025; ClinVar: uncertain significance; called by muse, mutect2
- EP400 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 158/294 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs773319689; called by mutect2, varscan2
- EWSR1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 166/490 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs764280754, COSV58423285; called by muse, varscan2
- FAM155A | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV65569724; called by muse, mutect2, varscan2
- FLYWCH1 | c.1961G>A p.R654H (on ENST00000253928 / NM_001308068.2; = p.R653H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 292/484 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs370312211; called by muse, varscan2
- GBE1 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 52/376 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV70096823; called by muse, mutect2, varscan2
- GCGR | c.1370A>G p.Q457R | Missense Mutation (SNP) | VAF 91/619 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs754349828; called by muse, varscan2
- GCNA | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390457046; called by muse, mutect2, varscan2
- GFRA3 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV51228104; called by muse, mutect2, varscan2
- GON4L | c.75C>G p.N25K | Missense Mutation (SNP) | VAF 197/402 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV55192548, COSV55199986; called by muse, mutect2, varscan2
- HORMAD1 | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 132/257 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777923537, COSV59270206; called by muse, mutect2, varscan2
- HS3ST3B1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 162/258 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1158347422; called by muse, varscan2
- IL3RA | c.183G>A p.P61= | Splice Region (SNP) | VAF 175/424 reads (41%) | catalogued as rs182203176, COSV58433905; called by muse, varscan2
- IL7R | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 62/592 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs767559651; called by muse, mutect2, varscan2
- IRX2 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 392/392 reads (100%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1156724415; called by muse, varscan2
- KEL | c.2057G>T p.S686I | Missense Mutation (SNP) | VAF 76/510 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV62338811; called by muse, varscan2
- KLF7 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1283605397; called by muse, mutect2, varscan2
- LRRC23 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 187/340 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs782037151; called by muse, varscan2
- LRRN2 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 237/471 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs918087646, COSV65783226; called by muse, mutect2, varscan2
- MBD4 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 213/284 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762115445, COSV99998957; called by muse, mutect2, varscan2
- MED15 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 351/546 reads (64%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.271); catalogued as rs776469364, COSV99488133; called by muse, mutect2, varscan2
- MED8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 82/338 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs755102418; called by muse, mutect2, varscan2
- MN1 | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 158/784 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as rs749180276; called by muse, mutect2, varscan2
- MUC2 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 18/650 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs952394179; called by muse, mutect2
- MYO3B | c.539A>T p.Q180L | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1463946955; called by muse, mutect2
- MYO5A | c.2166C>A p.D722E | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV62558508; called by muse, mutect2
- NAA10 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 115/863 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV63133850; called by muse, varscan2
- NLGN4X | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 212/562 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99324234; called by muse, mutect2, varscan2
- NOL4L | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 408/1208 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs1274462057, COSV62889222; called by muse, varscan2
- NOVA2 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 208/566 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs771307955, COSV54360198; called by muse, varscan2
- NPRL3 | c.1298G>A p.R433Q (on ENST00000611875 / NM_001077350.3; = p.R408Q on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/481 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs781225056, COSV54737481; called by muse, varscan2
- OIP5 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780737339; called by muse, varscan2
- OR2A7 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 102/1077 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1198026315; called by muse, varscan2
- OR52E8 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs760316487; called by muse, mutect2, varscan2
- PASD1 | c.229T>A p.L77I | Missense Mutation (SNP) | VAF 42/452 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV64856620; called by muse, mutect2
- PDCD6 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 63/535 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs370878298; called by muse, varscan2
- PHKA1 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 16/480 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV59809745; called by muse, mutect2
- PLAG1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs749464612, COSV57609638; called by muse, varscan2
- PLCB1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 128/600 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs777737218, COSV62043711; called by muse, mutect2, varscan2
- PLEKHG3 | c.1291C>T p.R431W (on ENST00000394691; = p.R487W on NM_001308147.2) | Missense Mutation (SNP) | VAF 197/269 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs767034301; called by muse, varscan2
- POTEC | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 352/352 reads (100%) | catalogued as rs1192374736, COSV62803844; called by muse, varscan2
- PRDM15 | c.2660A>G p.K887R | Missense Mutation (SNP) | VAF 80/354 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54155527; called by muse, mutect2, varscan2
- PXDNL | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 161/427 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs770252979, COSV100683091; called by muse, varscan2
- RBMXL3 | c.3180G>T p.R1060S | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs782800955; called by muse, mutect2, varscan2
- RECQL | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.818); catalogued as rs761204305; called by muse, mutect2, varscan2
- SCUBE1 | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs769603113; called by muse, mutect2, varscan2
- SERPINB3 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52194355; called by muse, mutect2, varscan2
- SKOR1 | c.1801G>T p.D601Y | Missense Mutation (SNP) | VAF 465/465 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781074505; called by muse, varscan2
- SLC2A2 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1276756236, COSV58585383; called by muse, mutect2, varscan2
- SLC6A8 | c.1553G>T p.W518L | Missense Mutation (SNP) | VAF 73/575 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs1569539454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPON1 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 218/318 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782102884; called by muse, varscan2
- SPTBN2 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 246/444 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.227); catalogued as rs766328275, COSV59461556; called by muse, varscan2
- STAT2 | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58476040; called by muse, mutect2, varscan2
- SV2A | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782169279, COSV64964464; called by muse, varscan2
- TAS1R2 | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 97/205 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV64743935; called by muse, mutect2, varscan2
- TMEM132D | c.2860G>T p.E954* | Nonsense Mutation (SNP) | VAF 75/368 reads (20%) | catalogued as COSV67160059; called by muse, mutect2, varscan2
- TMEM161A | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 236/680 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779335342; called by muse, mutect2, varscan2
- TPTE | c.523G>A p.V175I (on ENST00000618007 / NM_199261.4; = p.V157I on NM_199259.4) | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs755683317; called by muse, varscan2
- TTLL6 | c.1906G>A p.A636T (on ENST00000393382 / NM_001130918.3; = p.A329T on NM_173623.3) | Missense Mutation (SNP) | VAF 382/578 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs771002077; called by muse, varscan2
- TTN | c.7393G>A p.E2465K (on ENST00000591111; = p.E2419K on NM_003319.4) | Missense Mutation (SNP) | VAF 60/396 reads (15%) | PolyPhen probably damaging (0.994); catalogued as rs941805455; called by muse, mutect2, varscan2
- UBA1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 111/639 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1456448556; called by muse, mutect2, varscan2
- WEE2 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 243/505 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101285156; called by muse, mutect2, varscan2
- WIZ | c.2674C>T p.R892C (on ENST00000673675 / NM_001371589.1; = p.R155C on NM_021241.3) | Missense Mutation (SNP) | VAF 170/497 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs766856285, COSV99652572; called by muse, varscan2
- WNK2 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 128/470 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs753795828; called by muse, varscan2
- ZNF572 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs867154011; called by muse, mutect2
- ZNF728 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 137/396 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1199562870; called by muse, mutect2, varscan2
- ABCA13 | c.8429A>G p.H2810R | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCG8 | c.1591C>A p.H531N | Missense Mutation (SNP) | VAF 256/799 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- ABHD18 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAM19 | c.2783A>C p.K928T | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by mutect2, varscan2
- ADAM33 | c.575G>T p.S192I | Missense Mutation (SNP) | VAF 67/581 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFP | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 177/303 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AKR1C4 | c.719T>A p.V240D | Missense Mutation (SNP) | VAF 22/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ANGPT4 | c.1129T>G p.S377A | Missense Mutation (SNP) | VAF 68/1027 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.063); called by muse, mutect2
- ANKRD44 | c.1760T>G p.L587R | Missense Mutation (SNP) | VAF 184/340 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- AOC1 | c.1405T>G p.F469V | Missense Mutation (SNP) | VAF 62/514 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ARHGEF17 | c.1426A>T p.S476C | Missense Mutation (SNP) | VAF 94/516 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ASPG | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AXDND1 | c.2760A>C p.E920D | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- B2M | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- BRD3 | c.1348T>C p.S450P | Missense Mutation (SNP) | VAF 125/624 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- BTC | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 91/435 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C10orf71 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- CACNA1F | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 82/631 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CAND1 | c.1975C>G p.L659V | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC168 | c.19634A>T p.E6545V | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, varscan2
- CD320 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 303/468 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CENPN | c.184A>C p.S62R | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- CFAP47 | c.6773C>T p.P2258L | Missense Mutation (SNP) | VAF 97/296 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CFAP58 | c.1113A>C p.Q371H | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFAP97D1 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNKSR2 | c.767T>G p.I256S | Missense Mutation (SNP) | VAF 63/475 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN1 | c.1146_1147insAAAAC p.F383Kfs*12 | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | called by mutect2, pindel*, varscan2*
- COG1 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CRB1 | c.2785G>A p.G929R | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- CSE1L | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CTU1 | c.598T>C p.S200P | Missense Mutation (SNP) | VAF 101/604 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DCAF12L1 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 294/694 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX23 | c.1475G>T p.G492V | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- DDX53 | c.1892G>T p.S631I | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- DPP6 | c.2383dup p.I795Nfs*15 (on ENST00000377770 / NM_001364500.2; = p.I733Nfs*15 on NM_001936.5) | Frame Shift Ins (INS) | VAF 38/286 reads (13%) | called by mutect2, varscan2
- DYNC1I2 | c.409A>C p.K137Q | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EHMT2 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 16/520 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2
- EML1 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EML1 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ERAP2 | c.2137A>G p.R713G | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FBXO41 | c.1864T>G p.L622V | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCSK | c.2276A>C p.E759A | Missense Mutation (SNP) | VAF 41/647 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.549); called by muse, mutect2
- FLG | c.2494T>A p.S832T | Missense Mutation (SNP) | VAF 48/482 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.041); called by muse, mutect2
- GCGR | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 94/620 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, varscan2
- GRID2 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GRIN2D | c.3262G>T p.G1088* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- GRIP2 | c.1075T>C p.S359P (on ENST00000619221; = p.S262P on NM_001080423.4) | Missense Mutation (SNP) | VAF 67/609 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GYS2 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- HAGH | c.119A>C p.K40T | Missense Mutation (SNP) | VAF 67/425 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HAUS3 | c.1802T>G p.L601R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- HEATR6 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 66/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXB1 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 94/634 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, varscan2
- ITGB1BP2 | c.592T>A p.L198M | Missense Mutation (SNP) | VAF 64/570 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ITGB3 | c.1260+4A>C | Splice Region (SNP) | VAF 64/831 reads (8%) | called by muse, mutect2
- KIF1A | c.2525A>G p.D842G | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- KIR2DS4 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 152/154 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KIR3DL2 | c.616T>G p.L206V | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2
- KRTAP5-5 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 555/767 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); called by muse, varscan2
- LCOR | c.3829A>C p.S1277R | Missense Mutation (SNP) | VAF 78/459 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- LONRF2 | c.1946T>G p.L649R | Missense Mutation (SNP) | VAF 187/334 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- MAN2A2 | c.2150T>C p.V717A | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- MANF | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.261); called by muse, varscan2
- MAPRE1 | c.192A>C p.Q64H | Missense Mutation (SNP) | VAF 32/816 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- MMP21 | c.1382A>C p.K461T | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MPEG1 | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- MYBBP1A | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.796); called by muse, mutect2
- MYO18B | c.5165A>T p.E1722V | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NDRG3 | c.1084C>G p.P362A (on ENST00000349004 / NM_032013.4; = p.P350A on NM_022477.4) | Missense Mutation (SNP) | VAF 76/828 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- NDST4 | c.359T>A p.L120H | Missense Mutation (SNP) | VAF 53/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NKX2-2 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 113/967 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NLK | c.624C>A p.H208Q | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, varscan2
- NME8 | c.1221A>T p.E407D | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NOD1 | c.2540T>C p.L847P | Missense Mutation (SNP) | VAF 52/467 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NONO | c.824T>A p.I275N | Missense Mutation (SNP) | VAF 96/668 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.09); called by muse, varscan2
- NRF1 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 58/545 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NRK | c.4439C>A p.A1480D | Missense Mutation (SNP) | VAF 72/784 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- NRXN1 | c.329A>C p.N110T | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUMA1 | c.2792A>G p.E931G | Missense Mutation (SNP) | VAF 90/562 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ODAM | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- OGFOD1 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OLFM4 | c.407_410delinsCA p.N136Tfs*6 | Frame Shift Del (DEL) | VAF 164/429 reads (38%) | called by pindel, varscan2*
- OR2A2 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR2A2 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 56/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR2A2 | c.904A>T p.R302* | Nonsense Mutation (SNP) | VAF 59/431 reads (14%) | called by muse, mutect2, varscan2
- OR8U1 | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 100/582 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.297); called by muse, varscan2
- OTOP1 | c.1208T>G p.L403R | Missense Mutation (SNP) | VAF 79/511 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PCDHB13 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 607/695 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PHACTR3 | c.573A>C p.E191D | Missense Mutation (SNP) | VAF 59/688 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- PPP1CB | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 126/459 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPP1R10 | c.1080A>C p.E360D | Missense Mutation (SNP) | VAF 77/655 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRKAA2 | c.848A>C p.Y283S | Missense Mutation (SNP) | VAF 140/281 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PSKH2 | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 92/494 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); called by muse, varscan2
- PTGS2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 116/219 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, varscan2
- RAB17 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 45/551 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- REPS1 | c.1930G>A p.E644K (on ENST00000450536 / NM_001286611.2; = p.E643K on NM_031922.4) | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by mutect2, varscan2
- RIMS1 | c.1325A>T p.K442M | Missense Mutation (SNP) | VAF 96/600 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- RORB | c.542T>C p.L181P (on ENST00000396204 / NM_001365023.1; = p.L170P on NM_006914.4) | Missense Mutation (SNP) | VAF 86/469 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RPRD1B | c.979T>G p.*327Eext*26 | Nonstop Mutation (SNP) | VAF 98/467 reads (21%) | called by muse, mutect2, varscan2
- RRP12 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, varscan2
- RYR2 | c.10215C>G p.Y3405* | Nonsense Mutation (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- S1PR5 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 18/673 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- SCML2 | c.1003A>C p.T335P | Missense Mutation (SNP) | VAF 23/614 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- SCN3A | c.1930A>C p.M644L | Missense Mutation (SNP) | VAF 144/385 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SCNN1B | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 73/391 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SDC1 | c.217G>C p.A73P | Missense Mutation (SNP) | VAF 38/626 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.505); called by muse, mutect2
- SDK1 | c.2147T>A p.V716E | Missense Mutation (SNP) | VAF 157/496 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC13 | c.584A>C p.K195T (on ENST00000350697 / NM_183352.3; = p.K198T on NM_030673.4) | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.288); called by mutect2, varscan2
- SEC14L1 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 22/529 reads (4%) | called by muse, mutect2
- SF3B3 | c.1380G>A p.W460* | Nonsense Mutation (SNP) | VAF 219/387 reads (57%) | called by muse, mutect2, varscan2
- SFTPA1 | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 70/503 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, varscan2
- SGPP2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 320/557 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SHANK3 | c.2665C>T p.Q889* | Nonsense Mutation (SNP) | VAF 24/398 reads (6%) | called by muse, mutect2
- SHC4 | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- SHFL | c.786_809del p.D265_L272del | In Frame Del (DEL) | VAF 102/430 reads (24%) | called by mutect2, varscan2
- SLC2A2 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A7 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 346/920 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); called by muse, varscan2
- SLF1 | c.2065T>A p.L689M | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMARCAL1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ST3GAL6 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SV2C | c.650G>T p.R217M | Missense Mutation (SNP) | VAF 96/497 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVEP1 | c.1218T>A p.C406* | Nonsense Mutation (SNP) | VAF 73/333 reads (22%) | called by muse, mutect2, varscan2
- TANK | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D1 | c.3284T>G p.L1095R | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, varscan2
- TBC1D17 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 86/523 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TCP11L1 | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, varscan2
- TKT | c.521A>C p.K174T | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.287); called by muse, varscan2
- TMPRSS5 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 173/276 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2
- TNIP1 | c.1046dup p.T350Dfs*2 | Frame Shift Ins (INS) | VAF 61/273 reads (22%) | called by mutect2, pindel, varscan2
- TRHDE | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 280/554 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); called by muse, varscan2
- TRRAP | c.9311T>G p.V3104G (on ENST00000359863 / NM_001244580.1; = p.V3075G on NM_003496.3) | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTC34 | c.341C>G p.A114G | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.578); called by muse, mutect2
- TTC6 | c.3016C>A p.L1006I | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated (1); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- TTN | c.34523T>A p.V11508E (on ENST00000591111; = p.V10581E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- WDR48 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 11/401 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- WEE2 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 214/465 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- XPO6 | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZDHHC11 | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 526/795 reads (66%) | called by muse, mutect2, varscan2
- ZFPM2 | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZFYVE28 | c.1802A>T p.K601M | Missense Mutation (SNP) | VAF 102/565 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.887); called by muse, varscan2
- ZMYM2 | c.1858A>C p.S620R | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2
- ZNF160 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 55/406 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, varscan2
- ZNF316 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 204/584 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ZNF408 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 36/567 reads (6%) | called by muse, mutect2
- ZNF534 | c.412G>A p.A138T (on ENST00000332323 / NM_001143939.3; = p.A125T on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.629); called by muse, varscan2
- ZNF585A | c.757C>T p.Q253* (on ENST00000292841 / NM_001288800.2; = p.Q198* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 249/430 reads (58%) | called by muse, mutect2, varscan2
- ZNF727 | c.1040A>T p.K347I | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- ZNF862 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAM12 | c.1068C>T p.F356= | Silent (SNP) | VAF 220/394 reads (56%) | catalogued as rs778190289, COSV64106841; called by muse, varscan2
- ADAMTS9 | c.1233T>A p.I411= | Silent (SNP) | VAF 143/370 reads (39%) | called by muse, mutect2, varscan2
- ADCY9 | c.39C>T p.H13= | Silent (SNP) | VAF 45/348 reads (13%) | called by muse, mutect2, varscan2
- AGRP | c.73T>C p.L25= | Silent (SNP) | VAF 53/407 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.7953G>C p.V2651= | Silent (SNP) | VAF 131/314 reads (42%) | called by muse, varscan2
- BEST2 | c.405G>A p.S135= | Silent (SNP) | VAF 131/688 reads (19%) | catalogued as rs748960573, COSV50358545, COSV50368974; called by muse, varscan2
- BOD1L1 | c.5817A>G p.K1939= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- C2CD6 | c.1116G>A p.T372= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs895636226, COSV53791228; called by muse, mutect2
- C2orf92 | c.495T>C p.L165= | Silent (SNP) | VAF 109/340 reads (32%) | called by muse, mutect2, varscan2
- CADPS2 | c.754C>T p.L252= | Silent (SNP) | VAF 121/261 reads (46%) | called by muse, mutect2, varscan2
- CAND2 | c.3348C>T p.D1116= (on ENST00000456430 / NM_001162499.2; = p.D999= on NM_012298.3) | Silent (SNP) | VAF 36/410 reads (9%) | catalogued as rs754832586, COSV55988140; called by muse, mutect2
- CATSPER2 | c.1509G>A p.K503= (on ENST00000321596 / NM_001282309.3; = p.K505= on NM_172095.4) | Silent (SNP) | VAF 54/302 reads (18%) | called by muse, varscan2
- CCN6 | c.864T>G p.T288= | Silent (SNP) | VAF 16/590 reads (3%) | called by muse, mutect2
- CLEC18B | c.349T>C p.L117= | Silent (SNP) | VAF 88/540 reads (16%) | catalogued as COSV60577179; called by muse, varscan2
- COL4A2 | c.2472C>A p.G824= | Silent (SNP) | VAF 222/820 reads (27%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.1395T>G p.P465= | Silent (SNP) | VAF 47/385 reads (12%) | called by muse, mutect2, varscan2
- DGKQ | c.1323C>T p.P441= | Silent (SNP) | VAF 125/603 reads (21%) | catalogued as rs747567422; called by muse, mutect2, varscan2
- DLGAP3 | c.624A>G p.G208= | Silent (SNP) | VAF 98/555 reads (18%) | called by muse, mutect2, varscan2
- DRC7 | c.1032C>T p.H344= | Silent (SNP) | VAF 77/421 reads (18%) | called by muse, mutect2, varscan2
- EFCAB5 | c.30C>G p.L10= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as COSV57928555, COSV57935878; called by muse, varscan2
- EIF5AL1 | c.159C>T p.H53= | Silent (SNP) | VAF 205/425 reads (48%) | catalogued as rs1379612668, COSV101592809; called by muse, varscan2
- ETNPPL | c.384C>G p.G128= | Silent (SNP) | VAF 69/358 reads (19%) | called by muse, mutect2, varscan2
- FAM155A | c.879G>A p.E293= | Silent (SNP) | VAF 62/437 reads (14%) | called by muse, mutect2, varscan2
- FBN2 | c.318A>T p.G106= | Silent (SNP) | VAF 66/312 reads (21%) | called by muse, mutect2, varscan2
- FRMPD3 | c.3294T>A p.L1098= | Silent (SNP) | VAF 105/814 reads (13%) | called by muse, varscan2
- FUS | c.240C>T p.G80= | Silent (SNP) | VAF 42/480 reads (9%) | called by muse, mutect2
- GDPD1 | c.798C>T p.D266= | Silent (SNP) | VAF 96/221 reads (43%) | called by muse, mutect2, varscan2
- GLB1L | c.1768A>C p.R590= | Silent (SNP) | VAF 73/455 reads (16%) | catalogued as COSV55476862; called by muse, varscan2
- GPR3 | c.318G>A p.A106= | Silent (SNP) | VAF 256/530 reads (48%) | catalogued as rs756872209; called by muse, varscan2
- GRIN2D | c.3261A>G p.G1087= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- GTF3C3 | c.2100C>T p.P700= | Silent (SNP) | VAF 107/279 reads (38%) | catalogued as COSV99826751; called by muse, varscan2
- HTN3 | c.135A>C p.S45= | Silent (SNP) | VAF 90/266 reads (34%) | called by muse, mutect2, varscan2
- IQSEC2 | c.3171C>G p.V1057= (on ENST00000642864 / NM_001111125.3; = p.V852= on NM_015075.2) | Silent (SNP) | VAF 52/936 reads (6%) | called by muse, mutect2
- KCNA4 | c.1269G>T p.L423= | Silent (SNP) | VAF 86/409 reads (21%) | called by muse, mutect2, varscan2
- KCNH5 | c.33G>A p.P11= | Silent (SNP) | VAF 90/290 reads (31%) | catalogued as rs775018863; called by muse, mutect2, varscan2
- KLK12 | c.111G>T p.V37= | Silent (SNP) | VAF 113/622 reads (18%) | called by muse, mutect2, varscan2
- KRTAP10-6 | c.537G>A p.V179= | Silent (SNP) | VAF 324/764 reads (42%) | catalogued as rs781814007; called by muse, mutect2, varscan2
- LGALSL | c.228A>G p.S76= | Silent (SNP) | VAF 76/400 reads (19%) | called by muse, mutect2, varscan2
- MAGEA8 | c.330A>G p.E110= | Silent (SNP) | VAF 87/700 reads (12%) | called by muse, mutect2, varscan2
- MALRD1 | c.1407T>G p.T469= | Silent (SNP) | VAF 11/260 reads (4%) | called by muse, mutect2
- MARCKS | c.756C>T p.S252= | Silent (SNP) | VAF 191/589 reads (32%) | called by muse, mutect2, varscan2
- NAGPA | c.1446G>A p.L482= | Silent (SNP) | VAF 110/559 reads (20%) | called by muse, mutect2, varscan2
- NR4A1 | c.1050T>C p.P350= | Silent (SNP) | VAF 81/441 reads (18%) | called by muse, mutect2, varscan2
- NR6A1 | c.1330T>C p.L444= (on ENST00000487099 / NM_033334.4; = p.L439= on NM_001489.5) | Silent (SNP) | VAF 69/267 reads (26%) | called by muse, mutect2, varscan2
- OBSL1 | c.2625C>T p.G875= | Silent (SNP) | VAF 331/564 reads (59%) | catalogued as rs979869314, COSV54708844; called by muse, varscan2
- OR10G6 | c.111C>A p.G37= | Silent (SNP) | VAF 64/254 reads (25%) | called by muse, varscan2
- OR2A2 | c.903C>T p.H301= | Silent (SNP) | VAF 60/438 reads (14%) | called by muse, mutect2, varscan2
- OR4A16 | c.190T>C p.L64= | Silent (SNP) | VAF 77/421 reads (18%) | catalogued as COSV100125225, COSV59042593, COSV59042620; called by muse, mutect2, varscan2
- PCDHGA1 | c.1620G>A p.P540= | Silent (SNP) | VAF 318/319 reads (100%) | catalogued as rs768192242; called by muse, varscan2
- PCSK2 | c.1029C>T p.Y343= | Silent (SNP) | VAF 185/820 reads (23%) | catalogued as rs1441737223, COSV52740544; called by muse, mutect2, varscan2
- PIGQ | c.156G>A p.V52= | Silent (SNP) | VAF 292/710 reads (41%) | catalogued as rs1242906892, COSV99216526; called by muse, varscan2
- PLEKHH2 | c.837T>C p.S279= | Silent (SNP) | VAF 30/524 reads (6%) | called by muse, mutect2
- PRSS54 | c.117C>T p.Y39= | Silent (SNP) | VAF 138/379 reads (36%) | catalogued as rs1414039933, COSV54689347; called by muse, varscan2
- PSD2 | c.490C>T p.L164= | Silent (SNP) | VAF 142/545 reads (26%) | called by muse, mutect2, varscan2
- PTGDR | c.852C>T p.R284= | Silent (SNP) | VAF 100/100 reads (100%) | catalogued as rs768208384, COSV60094694; called by muse, varscan2
- PTX3 | c.759G>A p.E253= | Silent (SNP) | VAF 20/376 reads (5%) | called by muse, mutect2
- PXDN | c.2289C>T p.F763= | Silent (SNP) | VAF 111/675 reads (16%) | catalogued as rs892626373, COSV53230831; called by muse, mutect2, varscan2
- PXDNL | c.2373G>A p.A791= | Silent (SNP) | VAF 535/655 reads (82%) | called by muse, varscan2
- PXDNL | c.2254C>T p.L752= | Silent (SNP) | VAF 128/654 reads (20%) | catalogued as rs779475364; called by muse, varscan2
- RAPGEF4 | c.1336T>C p.L446= | Silent (SNP) | VAF 54/318 reads (17%) | catalogued as rs1559166624; called by muse, mutect2, varscan2
- RSPH10B | c.1683C>T p.L561= | Silent (SNP) | VAF 50/1042 reads (5%) | catalogued as rs756629077; called by muse, mutect2
- SFTPA1 | c.21C>A p.A7= | Silent (SNP) | VAF 70/497 reads (14%) | called by muse, varscan2
- SGCG | c.459A>T p.V153= | Silent (SNP) | VAF 22/434 reads (5%) | called by muse, mutect2
- SIM1 | c.294T>C p.D98= | Silent (SNP) | VAF 249/396 reads (63%) | catalogued as COSV53492476; called by muse, mutect2, varscan2
- SIX3 | c.711C>T p.R237= | Silent (SNP) | VAF 126/814 reads (15%) | catalogued as rs759831587, COSV99578109; called by muse, mutect2, varscan2
- SLC35B3 | c.354G>T p.V118= | Silent (SNP) | VAF 13/342 reads (4%) | called by muse, mutect2
- SLC7A8 | c.1377A>G p.G459= | Silent (SNP) | VAF 15/363 reads (4%) | catalogued as COSV100328601; called by muse, mutect2
- SPANXN2 | c.15T>G p.T5= | Silent (SNP) | VAF 47/379 reads (12%) | catalogued as COSV100979733, COSV65129075; called by muse, mutect2, varscan2
- SPEF2 | c.1986T>G p.A662= | Silent (SNP) | VAF 56/471 reads (12%) | called by muse, mutect2, varscan2
- SRRT | c.1185G>A p.K395= | Silent (SNP) | VAF 46/614 reads (7%) | catalogued as rs760128501; called by muse, mutect2
- STAMBPL1 | c.87A>C p.R29= | Silent (SNP) | VAF 68/361 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.21714T>C p.L7238= (on ENST00000367255 / NM_182961.4; = p.L7167= on NM_033071.3) | Silent (SNP) | VAF 267/416 reads (64%) | called by muse, mutect2, varscan2
- SYNPO2L | c.2412C>T p.N804= (on ENST00000394810 / NM_001114133.3; = p.N580= on NM_024875.5) | Silent (SNP) | VAF 58/510 reads (11%) | catalogued as rs769390297; called by muse, varscan2
- TANC2 | c.4167G>A p.Q1389= | Silent (SNP) | VAF 125/452 reads (28%) | called by muse, mutect2, varscan2
- TBC1D2B | c.2823C>T p.D941= | Silent (SNP) | VAF 203/420 reads (48%) | called by muse, varscan2
- TCF20 | c.387G>A p.Q129= | Silent (SNP) | VAF 316/686 reads (46%) | called by muse, varscan2
- TMEM201 | c.333G>A p.Q111= | Silent (SNP) | VAF 234/454 reads (52%) | called by muse, varscan2
- TMEM40 | c.612C>T p.F204= | Silent (SNP) | VAF 56/438 reads (13%) | catalogued as rs1019610401, COSV104392058; called by muse, mutect2, varscan2
- TRAJ53 | c.67A>T p.*23= | Silent (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- TRPC4AP | c.829T>C p.L277= | Silent (SNP) | VAF 64/588 reads (11%) | called by muse, varscan2
- UNC5C | c.1293A>T p.A431= | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- VWA3A | c.3183G>A p.K1061= | Silent (SNP) | VAF 56/369 reads (15%) | catalogued as rs1250471130; called by muse, mutect2, varscan2
- ZDBF2 | c.6957T>C p.P2319= | Silent (SNP) | VAF 147/354 reads (42%) | called by muse, mutect2, varscan2
- ZDHHC4 | c.469A>C p.R157= | Silent (SNP) | VAF 54/496 reads (11%) | called by muse, mutect2, varscan2
- ZIC3 | c.243C>T p.Y81= | Silent (SNP) | VAF 146/1055 reads (14%) | catalogued as COSV54976298; called by muse, varscan2
- ZKSCAN2 | c.2763C>T p.G921= | Silent (SNP) | VAF 18/453 reads (4%) | called by muse, mutect2
- ZSCAN18 | c.1458G>T p.A486= | Silent (SNP) | VAF 212/547 reads (39%) | catalogued as rs775951653, COSV53729926; called by muse, varscan2
- ZSCAN5C | c.306C>T p.V102= | Silent (SNP) | VAF 122/428 reads (29%) | called by muse, varscan2
- AC244258.1 | n.468T>G | RNA (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- CASR | c.1378-6182G>T | Intron (SNP) | VAF 79/325 reads (24%) | catalogued as COSV99948494; called by muse, mutect2, varscan2
- ERC2 | c.*1C>A | 3'UTR (SNP) | VAF 49/298 reads (16%) | catalogued as rs375029883; called by muse, varscan2
- IGFN1 | c.1242-1969G>T | Intron (SNP) | VAF 283/602 reads (47%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+14797T>G | Intron (SNP) | VAF 44/416 reads (11%) | called by muse, mutect2
- LIMK2 | c.1773-1419del | Intron (DEL) | VAF 102/821 reads (12%) | called by mutect2, pindel, varscan2
- SERP1 | c.160+54G>T | Intron (SNP) | VAF 25/528 reads (5%) | called by muse, mutect2
- SIMC1 | c.1678-261T>A | Intron (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2
- TBXAS1 | c.333+1803A>G | Intron (SNP) | VAF 67/559 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.10360+1450G>A | Intron (SNP) | VAF 73/337 reads (22%) | called by muse, mutect2, varscan2
